Surgical pathology report (de-identified scan), TCGA case TCGA-CM-5344, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-5344-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:

old with sigmoid colon cancer.

Specimens Submitted:

1: SP: Colon, terminal ileum, appendix; total colectomy

DIAGNOSIS:

1. SP: Colon, terminal ileum, appendix; total colectomy:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Sigmoid colon

Tumor Size:

Length is 3 cm

Width is 4 cm

Maximal thickness is 0.3 cm

Tumor Budding:

Focal

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubular adenoma

Deepest Tumor Invasion:

Subserosal adipose tissue and/or mesenteric fat

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Identified

Large Venous Invasion:

Not Identified

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

Tubular adenoma; number: 3

Non-Neoplastic Bowel:

Extensive melanosis coli

** Continued on next page **

[page 2 of 3]
Appendix:

Unremarkable

Lymph Nodes:

Number with metastasis: 3

Total number examined: 108

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N1b (Metastasis in 2-3 regional lymph nodes)

NOTE: THE IMMUNOHISTOCHEMICAL STAINING FOR THE TESTED DNA MISMATCH REPAIR PROTEINS (MLH1, MSH2, MSH6, PMS2) IS RETAINED IN THE TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1). The specimen is received fresh, labeled "total colectomy" and consists of a segment of terminal ileum, cecum with attached appendix, ascending, transverse, descending and sigmoid colon. The terminal ileum measures 12 cm in length and 3.5 cm in circumference at the proximal resected margin. The remaining colon measures 95.5 in length with a circumference of nine cm at the distal resected margin. The attached appendix measures 8 cm in length and averages 0.5 cm in diameter. The appendiceal and intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 2.5 cm in thickness. The specimen is opened to reveal a mass lesion measuring 3 cm in length and 4 cm in width. The mass is located in the sigmoid colon, 85 cm from the proximal margin and 7 cm from the distal margin. Sectioning shows that the tumor invades the muscularis propria and possibly the serosa. The depth of invasion is 0.3 cm grossly. The remaining mucosa shows two sessile polyp, measuring 0.5 x 0.5 x 0.3 and 0.3 x 0.2 x 0.2 cm. The attached adipose tissue is submitted for lymph node dissection and all identified lymph nodes are submitted. The colon is extensively sampled with representative sections submitted for permanent sections and for TFS.

Summary of sections:

PM - proximal margin shave

DM - distal margin shave

** Continued on next page **

[page 3 of 3]
T - tumor
P - polyps
A - appendix representative sections
RS -representative sections

Summary of Sections:

Part 1: SP: Colon, terminal ileum, appendix; total colectomy

Block	Sect.	Site	PCs
1		A	1
1		DM	1
23		LN	85
1		P	1
1		PM	1
10		RS	10
5		T	5

** End of Report **

Source: NCI Genomic Data Commons file 4bf46435-20eb-4893-8e6c-0476a484cd68 (TCGA-CM-5344.9AF94CFC-6EEF-4691-9DFB-C0F60CFEBDCB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).